Gene-level copy-number profile of tumor specimen TCGA-19-4068-01A from TCGA case TCGA-19-4068, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 68.3 years (24,945 days).
Specimen TCGA-19-4068-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.d11ceabf-3e4e-46c1-9ddc-42703feaea38.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-19-4068-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate.
https://portal.gdc.cancer.gov/files/dc2608d4-6ad1-4213-b709-233c2b28dc41

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 183; copy number 1: 5,032; copy number 2: 51,557; copy number 3: 3,008; copy number 4: 25; copy number 23: 14.

Homozygous deletions (total copy number 0; autosomes only): 183 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:152,091,712–152,094,009, 1 gene: AL078582.2.
- chr9:19,789,179–29,318,952, 130 genes (broad region; genes not listed).
- chr10:114,280,725–117,753,329, 51 genes (within-gene range 0–1): AC005383.1, AFAP1L2, RN7SL384P, AL133384.2, ABLIM1, AL133384.1, PPIAP19, AL137025.1, TAF9BP2, FAM160B1, RPL15P13, TRUB1, RNU6-1121P, LINC02626, ATRNL1, AC016042.1, NTAN1P1, GFRA1, AC012470.1, CCDC172, SNRPGP6, PNLIPRP3, HMGB3P8, RNU6-1090P, PNLIP, PNLIPP1, PNLIPRP1, PNLIPRP2, C10orf82, AC016825.1, HSPA12A, RPL5P27, ENO4, SHTN1, AC023283.1, AC012308.1, VAX1, MIR3663HG, MIR3663, RPL12P26, KCNK18, AL731557.1, SLC18A2, AL391988.1, PDZD8, AC005871.2, EMX2OS, EMX2, AC005871.1, AL356419.1, LINC02674.
- chr10:118,046,279–118,210,158, 1 gene (within-gene range 0–1): CASC2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 14 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,656,358–55,572,988, 14 genes, copy number 23 (within-gene range 3–23): RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1.

Autosomal genes at a single copy (total copy number 1): 5,032. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
